Gene-level copy-number profile of tumor specimen HTMCP-03-06-02170-01A from CGCI case HTMCP-03-06-02170, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02170-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 506c14f0-49e1-488f-a3cf-9de5fc8a5d06.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02170-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/d4a5b5cc-e963-435c-b990-672d60f01737

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 17; copy number 2: 3,008; copy number 3: 386; copy number 4: 23,811; copy number 5: 6,379; copy number 6: 13,719; copy number 7: 5,218; copy number 8: 3,773; copy number 9: 1,751; copy number 10: 227; copy number 11: 27; copy number 12: 26; copy number 15: 2; copy number 46: 5; copy number 90: 26; copy number 106: 8.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–2): AC104164.2, MIR548BB.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–4): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,072 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:42,143,238–42,332,548, 2 genes, copy number 9: EML4-AS1, EML4.
- chr2:45,651,345–46,187,990, 1 gene, copy number 9 (within-gene range 7–9): PRKCE.
- chr2:46,003,942–46,394,228, 7 genes, copy number 9: RPL26P15, AC017006.2, AC017006.1, RPL36AP14, Metazoa_SRP, EPAS1, LINC01820.
- chr2:105,144,113–105,438,513, 9 genes, copy number 9: LINC01918, GPR45, AC012360.2, TGFBRAP1, AC012360.1, AC012360.3, C2orf49, FHL2, AC108058.1.
- chr3:101,940,859–101,997,926, 3 genes, copy number 11: LINC02085, Y_RNA, AC106712.1.
- chr3:141,660,536–141,818,490, 6 genes, copy number 10: LINC02618, TPT1P3, AC112771.1, RNF7, AC112504.2, GRK7.
- chr3:160,495,007–198,123,232, 650 genes, copy number 9–15 (broad region; genes not listed).
- chr4:45,995,119–49,246,915, 48 genes, copy number 9–12: RN7SKP199, GABRG1, AC104072.1, GABRA2, AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr5:10,057,502–10,556,815, 31 genes, copy number 9: AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1.
- chr5:12,297,399–28,809,291, 185 genes, copy number 9 (broad region; genes not listed).
- chr5:28,897,785–29,003,357, 5 genes, copy number 9: AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4.
- chr6:53,153,795–53,153,898, 1 gene, copy number 9: RNU6-464P.
- chr8:39,451,045–39,522,852, 1 gene, copy number 9: ADAM3A.
- chr9:126,516,417–138,253,217, 422 genes, copy number 9–10 (broad region; genes not listed).
- chr10:4,650,158–4,848,062, 3 genes, copy number 9: MANCR, LINC00705, AKR1E2.
- chr10:23,343,957–23,345,181, 1 gene, copy number 9 (within-gene range 6–9): AL606469.1.
- chr10:79,661,394–79,826,594, 1 gene, copy number 12 (within-gene range 6–12): NUTM2B-AS1.
- chr10:79,825,902–79,850,878, 2 genes, copy number 12: AL135925.1, NUTM2E.
- chr11:101,890,674–103,895,271, 50 genes, copy number 9–106: ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693.
- chr12:72,087,266–72,670,758, 4 genes, copy number 10 (within-gene range 6–10): TRHDE, TRHDE-AS1, H3P35, CHCHD3P2.
- chr14:22,163,238–22,482,346, 33 genes, copy number 9 (within-gene range 5–9): TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 9: TRAC.
- chr20:31,257,664–55,075,140, 605 genes, copy number 9–10 (broad region; genes not listed).
- chr20:63,528,001–63,537,376, 1 gene, copy number 9: PTK6.

Autosomal genes at a single copy (total copy number 1): 17. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
